Gene-level copy-number profile of tumor specimen ALCH-B2T4-TTP1-A from ALCHEMIST case ALCH-B2T4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.1 years (22,315 days).
Specimen ALCH-B2T4-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1616e65e-23cb-4cd7-b859-004514369473.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2T4-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/4f5ee729-a90a-4cec-b245-0ff461df7280

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 609; copy number 1: 24,970; copy number 2: 31,392; copy number 3: 663; copy number 4: 886; copy number 5: 383; copy number 6: 2.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:41,478,775–41,484,683, 1 gene: EDN2.
- chr2:239,943,015–239,943,094, 1 gene (within-gene range 0–1): MIR4786.
- chr3:46,712,115–46,812,574, 8 genes (within-gene range 0–1): AC109583.1, PRSS50, PRSS46P, PRSS45P, AC109583.4, PRSS43P, AC109583.2, PRSS44P.
- chr3:50,419,781–50,419,899, 1 gene (within-gene range 0–1): RNA5SP131.
- chr3:52,373,652–52,374,882, 1 gene (within-gene range 0–1): PPP2R5CP.
- chr4:836,512–837,224, 1 gene: AC139887.3.
- chr4:4,086,638–4,175,238, 6 genes: AC116562.2, AC116562.1, OR7E103P, UNC93B4, OR7E99P, OR7E43P.
- chr4:8,858,715–8,860,827, 1 gene (within-gene range 0–1): AC116612.1.
- chr4:69,306,469–69,307,173, 1 gene (within-gene range 0–1): AC114786.3.
- chr5:177,801,204–177,803,344, 1 gene: AC140125.1.
- chr5:177,836,434–177,837,646, 1 gene (within-gene range 0–1): OR1X5P.
- chr6:32,517,353–32,560,022, 3 genes (within-gene range 0–1): HLA-DRB5, RNU1-61P, HLA-DRB6.
- chr9:34,546,524–34,546,996, 1 gene: AL160270.2.
- chr11:68,312,591–68,449,275, 1 gene: LRP5.
- chr12:49,539,030–49,558,337, 1 gene (within-gene range 0–2): KCNH3.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr14:92,905,697–92,935,285, 2 genes: LINC02287, CHGA.
- chr15:74,365,435–74,390,535, 3 genes (within-gene range 0–2): AC090826.1, AC090826.2, LINC02255.
- chr16:85,580,009–85,583,571, 1 gene: AC092127.2.
- chr17:17,776,686–17,837,011, 5 genes (within-gene range 0–1): SMCR5, AC122129.2, SREBF1, MIR6777, MIR33B.
- chr18:79,395,856–79,529,325, 6 genes (within-gene range 0–1): NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2.
- chr19:4,356,637–4,358,448, 1 gene (within-gene range 0–2): AC007292.2.
- chr19:4,363,789–4,364,640, 1 gene (within-gene range 0–1): AC007292.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 385 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:27,638,483–27,646,483, 2 genes, copy number 6: ERVK-28, AC112702.1.
- chr19:33,906,352–41,096,195, 383 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,678. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
